Gene-level copy-number profile of tumor specimen HTMCP-03-06-02145-01A from CGCI case HTMCP-03-06-02145, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.7 years (19,986 days).
Specimen HTMCP-03-06-02145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00e82629-6ff8-4382-913e-10317f793fd5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02145-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5cf5da6d-30b0-45cd-a913-81788da8156e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 2,782; copy number 2: 29,447; copy number 3: 20,056; copy number 4: 3,246; copy number 5: 2,644; copy number 6: 19; copy number 7: 66; copy number 8: 11; copy number 9: 26; copy number 18: 4; copy number 24: 50.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr8:7,295,014–7,385,558, 8 genes: FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C.
- chr8:12,374,366–12,375,546, 1 gene (within-gene range 0–1): AC087203.1.
- chr9:41,644,438–41,654,594, 4 genes: AL591926.7, AL591926.6, AL591926.5, AL591926.2.
- chr9:41,672,295–41,672,406, 1 gene (within-gene range 0–2): Y_RNA.
- chr9:42,384,805–42,714,539, 12 genes: FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr18:50,879,080–51,845,628, 14 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,818 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,533,749–120,355,148, 23 genes, copy number 7: GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:143,419,625–174,995,308, 1,100 genes, copy number 5 (broad region; genes not listed).
- chr1:248,323,630–248,937,043, 37 genes, copy number 5: OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:16,149,251–16,149,394, 1 gene, copy number 5: AC174048.1.
- chr3:120,908,072–121,424,761, 1 gene, copy number 5 (within-gene range 4–5): STXBP5L.
- chr3:121,356,991–180,213,108, 963 genes, copy number 5–6 (broad region; genes not listed).
- chr3:180,566,718–198,123,232, 405 genes, copy number 5 (broad region; genes not listed).
- chr12:67,709,047–72,670,758, 96 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr18:45,669,367–49,851,059, 95 genes, copy number 7–24 (within-gene range 1–24) (broad region; genes not listed).
- chr22:41,998,725–45,341,955, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,782. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
